Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6538, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6538-01A (Primary Tumor).

TCGA - D5 - 6538

Examination: Histopathological examination

Material: Total organ resection – colon and caecum

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: Cancer of the hepatic flexure.

Examination performed

Macroscopic description:

A 11,2 cm length of large intestine with a fragment of mesentery sized 16 x 9 x 3 cm, an 8 cm section of a and 5.5 cm appendix. Ulcerous tumour sized 5.4 x 6.9 x 1.8 cm in the mucosa. The lesion surrounds 100% of the intestine circumference, removed 9, 3 cm from the proximal incision, 3.1 cm from the distal incision, and 1.3 cm from the Bauhin's valve.

Microscopic description:

Adenocarcinoma tubulopapillare partim mucinosum (G3). Infiltratio carcinomatosa profunda tunicae muscularis propriae et telae adiposae mesenterii pericolicae. Incision lines are free of neoplastic lesions. Metastases carcinomatosa in lymphonodis (No X/XIV). Infiltratio carcinomatosa capsulae lymphonodorum et telae adiposae perinodalis. Emboliae carcinomatosa. Appendix - Appendicitis follicularis.

Histopathologic diagnosis:

Adenocarcinoma tubulopapillare partim mucinosum coli. Metastases carcinomatosa in lymphonodis (No X/XIV). Tubulopapillar and partially mucinous adenocarcinoma of the colon. Cancer metastases in lymph nodes (No X/XIV).

(G3, Dukes C, Astler-Coller C2, pT3, pN2).

Source: NCI Genomic Data Commons file 889477ce-94a7-4174-8bd8-a5be6e9b4ec3 (TCGA-D5-6538.092BF70B-2120-40EC-A98B-C72795D61660.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).